CCDI case PBCFZW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0b394bb9-3945-42eb-9fa9-3e1f8dc2456f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.4 years (3,781 days).

Biospecimens (3 samples)
- Sample 0DR1XK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR1YV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR1ZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
